Somatic mutation profile of tumor specimen TCGA-D8-A1XM-01A (aliquot TCGA-D8-A1XM-01A-21D-A14K-09) from TCGA case TCGA-D8-A1XM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.6 years (21,056 days).
Specimen TCGA-D8-A1XM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91c2068f-e518-472f-b70e-1c99a7c48853.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XM-10A (Blood Derived Normal), aliquot TCGA-D8-A1XM-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2429c93d-5330-4028-886c-e3838f2a1825

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH1C | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101565172; called by muse, mutect2
- AFDN | c.4529G>A p.S1510N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs974671882, COSV60053663; called by muse, mutect2, varscan2
- AP3B1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54894743; called by muse, mutect2, varscan2
- ATP2B2 | c.1913G>A p.R638Q (on ENST00000352432; = p.R604Q on NM_001683.5) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs774434270, COSV59494545; called by muse, mutect2, varscan2
- CACNG7 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55817780; called by muse, mutect2, varscan2
- CD2 | c.776A>C p.E259A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV65645021; called by muse, mutect2, varscan2
- COL11A1 | c.2295+1G>A p.X765_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV62200747; called by muse, mutect2, varscan2
- DCAF1 | c.2060A>G p.N687S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1553632324, COSV60047213; called by muse, mutect2, varscan2
- DCD | c.151T>A p.L51I | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.87); catalogued as COSV53202564; called by muse, mutect2, varscan2
- DDX18 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV54309073; called by muse, mutect2, varscan2
- DGKB | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs747038198, COSV51762576; called by muse, mutect2, varscan2
- DIAPH2 | c.1040T>A p.I347K | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61295533; called by muse, mutect2, varscan2
- DPP4 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV62110509; called by muse, mutect2, varscan2
- DST | c.12737G>A p.R4246Q (on ENST00000361203 / NM_001374722.1; = p.R1834Q on NM_015548.5) | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776588668, COSV55045347; called by muse, mutect2, varscan2
- EP300 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54347142; called by muse, mutect2, varscan2
- GMPPB | c.1036C>G p.H346D (on ENST00000308388 / NM_021971.4; = p.H373D on NM_013334.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100246507; called by muse, mutect2
- GPSM1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1249157164, COSV61305951; called by muse, mutect2
- GRID1 | c.2233G>A p.V745M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs747770345, COSV60044244; called by muse, mutect2, varscan2
- ISLR | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV51435699; called by muse, mutect2, varscan2
- KLHL17 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58533896; called by muse, mutect2, varscan2
- KRT6B | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as rs756538750, COSV52881720; called by muse, mutect2, varscan2
- LRRC41 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as COSV58442799; called by muse, mutect2, varscan2
- MED23 | c.3499C>T p.R1167* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV63437404; called by muse, mutect2, varscan2
- MXRA5 | c.5505G>T p.K1835N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs200995587, COSV54253465; called by muse, mutect2, varscan2
- MYO1C | c.2065C>T p.R689W (on ENST00000648651 / NM_001080779.2; = p.R654W on NM_033375.5) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs761399446, COSV62998234; called by muse, mutect2, varscan2
- NLGN4X | c.2125A>T p.R709W | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV52039927; called by muse, mutect2, varscan2
- NUDT12 | c.1079-1G>A p.X360_splice | Splice Site (SNP) | VAF 44/166 reads (27%) | catalogued as COSV50093382; called by muse, mutect2, varscan2
- OR4C15 | c.884C>A p.S295Y (on ENST00000314644; = p.S241Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV58951078; called by muse, mutect2, varscan2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs776329515; called by mutect2, varscan2
- RPS4X | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV60182125; called by muse, mutect2, varscan2
- SEC23IP | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV64833423; called by muse, mutect2, varscan2
- SLC22A16 | c.169A>C p.N57H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100397335; called by muse, mutect2, varscan2
- SMG1 | c.9647C>A p.S3216* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV67175176; called by muse, mutect2, varscan2
- SORL1 | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52754570; called by muse, mutect2, varscan2
- WEE1 | c.1752G>T p.L584F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55198626; called by muse, mutect2, varscan2
- XPC | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53208117; called by muse, mutect2, varscan2
- ZBTB4 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV100263640, COSV60984580; called by muse, mutect2, varscan2
- ZFP14 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54205452; called by muse, mutect2, varscan2
- MTRF1L | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF518A | c.1660_1667del p.S554Ifs*15 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- ADGRG3 | c.225G>A p.E75= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV59652963; called by muse, mutect2, varscan2
- AMBRA1 | c.219G>A p.V73= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV54060121; called by muse, mutect2, varscan2
- CILP | c.882G>A p.L294= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56026059, COSV56028552; called by muse, mutect2, varscan2
- DOCK7 | c.4665C>G p.L1555= (on ENST00000635253 / NM_001367561.1; = p.L1524= on NM_033407.3) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV52023762, COSV99222629; called by muse, mutect2, varscan2
- F8 | c.1800G>A p.E600= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1353676215, CM080293, COSV64271524, COSV64279517; called by muse, mutect2, varscan2
- FAM78B | c.72C>T p.C24= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV57979442; called by muse, mutect2, varscan2
- GPR142 | c.396C>T p.H132= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs1417803007, COSV59520650; called by muse, mutect2, varscan2
- HTR2A | c.753G>T p.V251= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs927684489, COSV66328617; called by muse, mutect2, varscan2
- IGSF3 | c.1341C>T p.I447= (on ENST00000369486 / NM_001007237.3; = p.I467= on NM_001542.4) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1384453989, COSV100604358, COSV100604844; called by muse, mutect2
- INPP4A | c.2874G>A p.L958= (on ENST00000074304 / NM_001134224.1; = p.L919= on NM_004027.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV50844377; called by muse, mutect2, varscan2
- LOXL3 | c.1149C>T p.L383= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV51210066, COSV51216391; called by muse, mutect2, varscan2
- MED12L | c.2661C>A p.L887= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV56388749, COSV56400470; called by muse, mutect2, varscan2
- PNLDC1 | c.870C>T p.L290= | Silent (SNP) | VAF 68/119 reads (57%) | catalogued as COSV51705553, COSV99277050; called by muse, mutect2, varscan2
- ZMYM3 | c.3483C>T p.Y1161= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs757104013, COSV58738224; called by muse, mutect2, varscan2
- DENND10P1 | n.671C>G | RNA (SNP) | VAF 41/138 reads (30%) | called by muse, mutect2, varscan2
